MMRF case MMRF_2425 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/52964e75-33e0-48ca-bb2a-f5156c8cb87d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.0 years (20,089 days); ISS stage: II; Days to last known disease status: 700 days (1.9 years); Days to last follow up: 700 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 225 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days; Days to treatment end: 232 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 233 days; Days to treatment end: 233 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 344 days; Days to treatment end: 521 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 521 days (1.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 1): M Protein 8.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 42.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 6.98 g/L; Immunoglobulin A 35.9 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 459 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 33 g/L; Total Protein 8.6 g/dL; Glucose 6.49 mmol/L; C-Reactive Protein 0.33 mg/dL.
- Day 78 (ECOG 1): M Protein 0.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 4.29 g/L; Immunoglobulin A 10.9 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 357 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 8.42 mmol/L.
- Day 169 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 488 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 6.77 mmol/L.
- Day 248 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 4.94 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 6.16 mmol/L.
- Day 344 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Immunoglobulin G 6.72 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 340 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 6.38 mmol/L.
- Day 430 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.93 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 6.6 mmol/L.
- Day 521 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.77 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 2.43 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 11.7 mmol/L.
- Day 604 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.39 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 3.35 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.17 µg/mL; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.1 mmol/L; Albumin 33 g/L; Total Protein 6.5 g/dL; Glucose 8.53 mmol/L.
- Day 700 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.57 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 3.54 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 6.33 mmol/L.

Other clinical attributes
- Day -11: Weight: 86 kg; Height: 185 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2425_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_2425_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
